Somatic mutation profile of tumor specimen TARGET-10-PATENL-09A (aliquot TARGET-10-PATENL-09A-01D) from TARGET case TARGET-10-PATENL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,345 days).
Specimen TARGET-10-PATENL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fbb6db9-190f-41d6-b4f4-984195c1a568.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATENL-10A (Blood Derived Normal), aliquot TARGET-10-PATENL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1754e8cb-2bac-4255-bc20-64480f2f0a54

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHF6 | c.673C>T p.R225* (on ENST00000332070 / NM_032458.3; = p.R226* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 56/63 reads (89%) | catalogued as rs1556018932, COSV59699600; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKL3 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs776106778, COSV54739704; called by muse, mutect2, varscan2
- PPM1N | c.441_442insCCCTAGATATAGA p.D148Pfs*2 | Nonsense Mutation (INS) | VAF 11/39 reads (28%) | catalogued as COSV55592645; called by mutect2, pindel, varscan2
- PPP1R16B | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1356816150, COSV55374369; called by muse, mutect2, varscan2
- PXDN | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53227401; called by muse, mutect2, varscan2
- ZBTB16 | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60089398; called by muse, mutect2, varscan2
- ZNF618 | c.925C>T p.R309C (on ENST00000374126 / NM_001318042.2; = p.R277C on NM_001318040.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.14); catalogued as rs775760238; called by muse, mutect2, varscan2
- OR2H2 | c.811T>C p.F271L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MLPH | c.1281G>A p.A427= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs202229121, COSV52820316; called by muse, mutect2, varscan2
- CLEC16A | c.1815+83C>T | Intron (SNP) | VAF 34/75 reads (45%) | catalogued as rs868292891; called by muse, mutect2, varscan2
